Gene-level copy-number profile of tumor specimen TCGA-CN-6023-01A from TCGA case TCGA-CN-6023, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 73.3 years (26,769 days).
Specimen TCGA-CN-6023-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.f92330e1-857f-49a0-af68-27a284a784ad.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-6023-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a54d1c9a-0a41-4dce-a209-813bb59188b9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 98; copy number 1: 321; copy number 2: 27,619; copy number 3: 17,318; copy number 4: 6,845; copy number 5: 5,623; copy number 6: 552; copy number 7: 424; copy number 8: 342; copy number 10: 566; copy number 13: 28; copy number 21: 78.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-6023-01A-11D-1682-01): tumor purity 0.36, ploidy 2.74, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 98 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,898,423–141,208,376, 4 genes: LRRC57P1, Y_RNA, RNU6-904P, RPS16P3.
- chr3:74,101,349–86,125,287, 89 genes (broad region; genes not listed).
- chr4:21,582,096–21,719,026, 3 genes: AC096576.3, AC096576.1, AC096576.2.
- chr6:161,353,679–161,446,016, 2 genes: AL132982.1, AL138716.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,613 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:118,883,046–248,919,946, 2,682 genes, copy number 5–21 (within-gene range 2–21) (broad region; genes not listed).
- chr2:94,912,432–125,823,315, 584 genes, copy number 5 (broad region; genes not listed).
- chr3:135,925,891–198,222,513, 1,088 genes, copy number 6–13 (broad region; genes not listed).
- chr5:58,198–2,715,237, 80 genes, copy number 5 (broad region; genes not listed).
- chr5:6,134,303–23,329,892, 260 genes, copy number 5 (broad region; genes not listed).
- chr5:25,187,800–25,324,386, 1 gene, copy number 6 (within-gene range 4–6): LINC02211.
- chr5:25,218,973–45,895,970, 304 genes, copy number 5–6 (broad region; genes not listed).
- chr6:62,460,940–63,779,336, 19 genes, copy number 5: DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3.
- chr6:63,797,189–63,857,769, 3 genes, copy number 5: AL354719.1, SCAT8, GCNT1P4.
- chr9:14,475–10,612,723, 145 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr9:9,799,423–43,045,120, 629 genes, copy number 6–8 (broad region; genes not listed).
- chr10:20,350,049–38,783,108, 337 genes, copy number 5 (broad region; genes not listed).
- chr12:38,274,448–72,670,758, 958 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:73,820,315–108,250,537, 523 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
